Surgical pathology report (de-identified scan), TCGA case TCGA-AA-3941, project TCGA-COAD (Colon Adenocarcinoma), tissue source site Indivumed, specimen TCGA-AA-3941-01A (Primary Tumor).

Diagnosis:

1. and 3. Right hemicolectomy preparation with tumor-free oral and aboral resection margins and including an ulcerated, moderately differentiated double carcinoma of the colon (ascending colon pT4 L1 V0 R0 and left flexure pT3 L1 V0 R0) with two local lymph node metastases (pN1b 3/41) (1.) and with hepatic spread (pM1a [REDACTED] (3.).

Source: NCI Genomic Data Commons file b74f3662-6180-433c-a9e2-2df031815b9b (TCGA-AA-3941.3360F9BC-C4D0-45FA-B6C4-26182ADB7F5F.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).